Gene-level copy-number profile of tumor specimen ALCH-B2YI-TTP1-A from ALCHEMIST case ALCH-B2YI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 65.0 years (23,745 days).
Specimen ALCH-B2YI-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56f64676-6d07-4eb2-be30-71768654f331.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2YI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/11148859-dfe4-4eed-b630-8b0567aefb8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 922; copy number 1: 19,596; copy number 2: 35,574; copy number 3: 2,561; copy number 4: 22; copy number 5: 10; copy number 6: 7; copy number 7: 71; copy number 8: 1; copy number 9: 45; copy number 10: 18; copy number 11: 26; copy number 16: 25.

Homozygous deletions (total copy number 0; autosomes only): 403 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,991,134–8,122,702, 4 genes: AL034417.4, ERRFI1, AL034417.2, AL034417.1.
- chr2:89,330,110–89,600,680, 2 genes: IGKV2-40, 5S_rRNA.
- chr2:241,849,884–241,858,894, 1 gene: PDCD1.
- chr3:195,843,986–195,844,596, 1 gene (within-gene range 0–2): KIF3AP1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:168,194,358–168,240,715, 3 genes: AL611929.1, AL606970.4, AL606970.2.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr8:737,628–1,708,476, 1 gene (within-gene range 0–1): DLGAP2.
- chr8:1,246,789–7,187,316, 83 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:7,272,148–7,896,716, 47 genes: FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A.
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–1): DEFB108A.
- chr9:12,134–1,057,552, 28 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2.
- chr9:8,314,246–10,612,723, 10 genes (within-gene range 0–1): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2.
- chr9:19,507,452–25,938,434, 92 genes (broad region; genes not listed).
- chr9:60,914,407–61,666,386, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:65,189,995–65,193,610, 1 gene: BMS1P12.
- chr9:127,397,138–127,408,424, 1 gene: SLC2A8.
- chr9:127,505,339–127,578,989, 1 gene: NIBAN2.
- chr11:2,129,112–2,161,209, 6 genes (within-gene range 0–2): IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS.
- chr11:2,173,063–2,173,138, 1 gene: MIR4686.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:123,262,060–123,262,402, 1 gene: AC068768.1.
- chr15:25,159,221–25,184,387, 10 genes (within-gene range 0–1): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8.
- chr15:25,194,921–25,238,067, 24 genes (within-gene range 0–1): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr15:25,243,614–25,249,279, 4 genes (within-gene range 0–1): SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr16:31,975,803–32,003,728, 1 gene: AC142381.3.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:4,583,999–4,608,319, 1 gene: SMTNL2.
- chr17:82,018,702–82,065,887, 9 genes: CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.
- chr18:79,340,258–80,033,949, 21 genes (within-gene range 0–1): AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, HSBP1L1, TXNL4A.
- chr19:18,418,864–18,443,597, 3 genes (within-gene range 0–1): SSBP4, ISYNA1, AC010335.1.
- chr19:18,448,275–18,448,805, 2 genes (within-gene range 0–1): AC010335.2, AC010335.3.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–1): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr19:50,723,364–50,725,718, 1 gene: CLEC11A.
- chr21:42,102,134–42,108,534, 1 gene (within-gene range 0–1): UMODL1-AS1.
- chr22:20,129,456–20,283,246, 6 genes: ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286.
- chr22:37,570,248–37,582,616, 2 genes: LGALS2, Metazoa_SRP.
- chr22:43,232,141–43,239,010, 1 gene (within-gene range 0–1): Z82214.1.
- chr22:48,489,553–48,850,912, 3 genes (within-gene range 0–1): TAFA5, Z84468.1, MIR4535.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 202 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:155,412,596–155,781,485, 8 genes, copy number 5: AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.1, RBM33.
- chr9:65,282,101–65,285,209, 1 gene, copy number 8: FOXD4L5.
- chr11:85,628,573–89,999,741, 112 genes, copy number 7–9 (broad region; genes not listed).
- chr11:90,972,316–91,234,388, 6 genes, copy number 10 (within-gene range 1–10): AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748.
- chr11:95,150,539–95,234,391, 3 genes, copy number 6: AP000787.1, SESN3, AP000787.3.
- chr11:101,451,564–102,880,846, 37 genes, copy number 10–16: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1.
- chr15:21,405,401–21,877,735, 26 genes, copy number 11: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P.
- chr15:22,125,511–22,126,434, 1 gene, copy number 6 (within-gene range 2–6): OR4N3P.
- chr15:22,194,885–22,202,734, 2 genes, copy number 6: IGHV1OR15-4, AC025884.3.
- chr16:33,533,816–33,570,935, 4 genes, copy number 7: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr19:46,826,895–46,850,846, 2 genes, copy number 5: AC008622.1, AP2S1.

Autosomal genes at a single copy (total copy number 1): 17,268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
